CCDI case PBCING — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Testis.
https://portal.gdc.cancer.gov/cases/090f4a3e-fb71-4de5-bbd9-371221eb12ab

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 17.9 years (6,545 days).

Biospecimens (2 samples)
- Sample 0DSW9J: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DSWA0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
